Somatic mutation profile of tumor specimen MP2PRT-PAUYTC-TMP1-A (aliquot MP2PRT-PAUYTC-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUYTC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,568 days).
Specimen MP2PRT-PAUYTC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e328a78-0191-48f9-b3e4-ce28122ba3db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYTC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYTC-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f5d0c9c-c72e-430f-b25f-a5750de83c9e

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN2 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541842635, CM148688, COSV52521856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARSF | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 27/562 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- FIGN | c.583C>A p.H195N | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.528); called by muse, mutect2
- FSBP | c.760G>T p.G254* | Nonsense Mutation (SNP) | VAF 104/343 reads (30%) | called by muse, mutect2, varscan2
- NHSL2 | c.539A>G p.Q180R (on ENST00000510661; = p.Q546R on NM_001013627.2) | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- RMDN3 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 107/263 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TNFRSF11A | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 134/301 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- EXOC7 | c.705G>A p.K235= | Silent (SNP) | VAF 158/323 reads (49%) | catalogued as COSV100135905; called by muse, mutect2, varscan2
- IRS2 | c.2868G>A p.S956= | Silent (SNP) | VAF 128/585 reads (22%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58841963 C>T | 5'Flank (SNP) | VAF 87/275 reads (32%) | catalogued as rs939055726; called by muse, mutect2, varscan2
